Surgical pathology report (de-identified scan), TCGA case TCGA-CC-5260, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site ILSBio, specimen TCGA-CC-5260-01A (Primary Tumor).

[page 1 of 3]
1CD-0-3

Hepatocarcinoma 8170/3

Site: Liver C22-0 1/28/11 JW

ID#:

Pathology Form

Specimen Information

Collected by: _____ Date: _____ Time: _____

Preserved by: _____ Date: _____ Time: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
12 min		13 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Liver tumor	10 x 9 x 7 cm		5 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT ₄ N ₀ M ₀		Stage: III	

Notes:

[page 2 of 3]
ID#:

Microscopic Description

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse			☒		Streaming						
Mosaic					Storiform						
Necrosis			☒		Fibrosis						
Lymphocytic Infiltration					Palisading						
Vascular Invasion					Cystic Degeneration						
Clusterized					Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						
Cellular Differentiation											
Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamous Cell			Glandular cell	☒		Round Cell			Large Cell		
Spindle Cell			Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		
Cellular Differentiation: Well Moderate Poor ☒											
Nuclear Appearance											
Nuclear Atypia:						0	I	II	III		
Aniso Nucleosis							☒				
Hyperchromatism								☒			
Nucleolar Prominent								☒			
Multinucleated Giant Cell								☒			
Mitotic Activity								☒			
Nuclear Grade:											

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Hepato carcinoma Grade: III

Comments: (Hepato - cholangio carcinoma)

Principal Investigator

Pathologist

Date

[page 3 of 3]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse			✓	Streaming			
Mosaic		X	✓	Storiform			
Necrosis			✓	Fibrosis			
Lymphocytic Infiltration		✓		Palisading			
Vascular Invasion			✓	Cystic Degeneration			
Clusterized		✓		Bleeding			
Alveolar Formation			✓	Myxoid Change			
Indian File			✓	Psammoma/Calcification			

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	✓		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	✓		Fibroblast			Small Cell		
Keratin			Secretion	✓		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	✓		Lipoblast			Inflam. Cell		
Pearl			Gland formation	✓		Myoblast			Plasma Cell		

Otherwise Specified: 1, 50%, 2, 50%, 3, 50%, 4, 50%

2. Cellular Differentiation:

Well	Moderately	Poor

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis			✓	
Hyperchromatism		✓		
Nucleolar Prominent		✓		
Multinucleated Giant Cell		✓		
Mitotic Activity		✓		
Nuclear Grade		X		

Histological Diagnosis: Hepatocellular Carcinoma, G1

Comments: _____

Date _____

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RESEARCH USE ONLY).

Source: NCI Genomic Data Commons file 5591ad29-4fbd-45ce-bee7-a55c3dcc33fb (TCGA-CC-5260.2E6A53F8-D019-4B4A-894F-CF21BEE91EDD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).